Somatic mutation profile of tumor specimen TCGA-58-8388-01A (aliquot TCGA-58-8388-01A-11D-2323-08) from TCGA case TCGA-58-8388, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 60.1 years (21,949 days).
Specimen TCGA-58-8388-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9aa7db6-fad1-4b18-aedd-03561f64acd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-58-8388-10A (Blood Derived Normal), aliquot TCGA-58-8388-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53c73e9a-6250-45ca-b748-f2da3ee8bd45

The open-access MAF lists 199 somatic variants for this specimen: 153 protein-altering or splice-affecting, 42 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 123, Silent 42, Nonsense Mutation 16, Frame Shift Del 6, Splice Site 6, Intron 3, Splice Region 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOTCH3 | c.145T>C p.C49R | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555730197, CM073243, CM106868, COSV99656239; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 24/43 reads (56%) | hotspot (GDC flag); catalogued as CM971503, COSV52676850, COSV52715987, COSV52740951; called by muse, mutect2, varscan2
- ACRBP | c.275C>A p.S92Y | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99975978; called by muse, mutect2, varscan2
- ACSM3 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs540980063, COSV99184133; called by muse, mutect2, varscan2
- ADRA2A | c.616A>T p.N206Y | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99701502; called by muse, mutect2, varscan2
- AJAP1 | c.686T>C p.M229T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100981526; called by mutect2, varscan2
- AKAP17A | c.1633G>T p.G545C | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100001960; called by muse, mutect2, varscan2
- AL592490.1 | c.2644G>T p.E882* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | catalogued as COSV69427958, COSV69428014; called by muse, mutect2, varscan2
- AP2B1 | c.299C>G p.P100R | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99250954; called by muse, mutect2
- ARFGAP2 | c.1399G>T p.G467W | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99561763; called by muse, mutect2, varscan2
- ARPC5L | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as COSV99414511; called by muse, mutect2, varscan2
- ARPP21 | c.2062G>A p.G688R | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV51798213; called by muse, mutect2, varscan2
- ASCC3 | c.2703+1G>A p.X901_splice | Splice Site (SNP) | VAF 44/114 reads (39%) | catalogued as COSV100225371; called by muse, mutect2, varscan2
- AUH | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.888); catalogued as COSV100342156; called by muse, mutect2, varscan2
- B4GALNT4 | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs751628641, COSV100327259; called by muse, mutect2, varscan2
- BCL2L10 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as COSV99548512; called by muse, mutect2, varscan2
- BRWD3 | c.1194G>T p.W398C | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100955755; called by muse, mutect2, varscan2
- CASP1 | c.1172G>C p.R391T (on ENST00000436863 / NM_033292.4; = p.R370T on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99507283; called by muse, mutect2, varscan2
- CCDC144A | c.209A>G p.D70G | Missense Mutation (SNP) | VAF 96/159 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV100501970; called by muse, mutect2, varscan2
- CCDC66 | c.622G>T p.E208* (on ENST00000394672 / NM_001353147.1; = p.E174* on NM_001012506.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 30/50 reads (60%) | catalogued as COSV100413769; called by muse, mutect2, varscan2
- CCDC88C | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as rs757076773, COSV101104686; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCIN | c.1501A>T p.T501S | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as COSV100631751; called by muse, mutect2, varscan2
- CCR6 | c.92C>A p.S31Y | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.078); catalogued as COSV100551004; called by muse, mutect2, varscan2
- CHST1 | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.216); catalogued as COSV100346070; called by muse, mutect2, varscan2
- CIP2A | c.1502A>G p.Y501C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99842689; called by muse, mutect2, varscan2
- COL11A1 | c.3125G>T p.G1042V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100615445, COSV62185668; called by muse, mutect2, varscan2
- COL11A1 | c.3124G>T p.G1042* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as CM107734, COSV100615448; called by muse, mutect2, varscan2
- COL12A1 | c.5986C>T p.P1996S | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV100485541; called by muse, mutect2, varscan2
- CPNE5 | c.320C>A p.S107Y | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV99782513; called by muse, varscan2
- CSF2RA | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 230/436 reads (53%) | catalogued as COSV100817537; called by muse, mutect2, varscan2
- CSF2RA | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 90/309 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs1418501378, COSV100817539; called by muse, mutect2, varscan2
- CSMD3 | c.1281A>C p.R427S | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.916); catalogued as COSV99827653; called by muse, mutect2, varscan2
- DCT | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 28/59 reads (47%) | catalogued as rs148575940; called by muse, mutect2, varscan2
- DDX6 | c.147C>G p.N49K | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.011); catalogued as rs769816474, COSV99870156; called by muse, mutect2, varscan2
- DGCR2 | c.1193G>C p.G398A | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99593371; called by muse, mutect2, varscan2
- DLL3 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99218857; called by muse, varscan2
- DMD | c.7315A>T p.T2439S | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100626220; called by muse, mutect2, varscan2
- DPH2 | c.20G>A p.S7N | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99356279; called by muse, mutect2, varscan2
- DSG4 | c.1813A>T p.T605S | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100355502; called by muse, mutect2, varscan2
- DYSF | c.1378A>T p.R460W | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99245050; called by muse, mutect2, varscan2
- EFCAB3 | c.1135A>G p.T379A | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs780684183, COSV100540066; called by muse, mutect2, varscan2
- EHBP1 | c.2026G>T p.D676Y | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV99860274; called by muse, mutect2, varscan2
- EPHA7 | c.472G>T p.G158C | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100992368; called by muse, mutect2, varscan2
- EPHX1 | c.51G>T p.W17C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); catalogued as COSV99688783; called by muse, mutect2, varscan2
- ERN2 | c.1087C>G p.H363D | Missense Mutation (SNP) | VAF 65/328 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99890827; called by muse, mutect2, varscan2
- ETAA1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV99712622; called by muse, mutect2, varscan2
- FAM47C | c.1004C>A p.P335H | Missense Mutation (SNP) | VAF 58/89 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100792354; called by muse, mutect2, varscan2
- FAM83B | c.731A>G p.Y244C | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100174144; called by muse, mutect2, varscan2
- FBXO45 | c.392C>G p.T131S | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100290929; called by muse, mutect2, varscan2
- FBXW10 | c.1416C>A p.S472R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs558549771, COSV100111266; called by muse, mutect2, varscan2
- FGFR1 | c.746-1G>C p.X249_splice (on ENST00000447712 / NM_023110.3; = p.X247_splice on NM_015850.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 79/148 reads (53%) | catalogued as COSV100247565; called by muse, mutect2, varscan2
- FNDC1 | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as COSV99795179; called by muse, mutect2, varscan2
- FREM2 | c.9317G>T p.S3106I | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.012); catalogued as COSV99747362; called by muse, varscan2
- GH2 | c.403A>T p.N135Y | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.802); catalogued as COSV100236866; called by muse, mutect2, varscan2
- GPR45 | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 89/263 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV51522903; called by muse, mutect2, varscan2
- H1-5 | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 103/303 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100137743; called by muse, mutect2, varscan2
- H2BC15 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs746829199, COSV100356920; called by muse, mutect2, varscan2
- HDAC9 | c.3031T>G p.W1011G (on ENST00000441542 / NM_178425.3; = p.W1008G on NM_178423.3) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101286557; called by muse, varscan2
- HMGCS2 | c.323C>A p.T108K | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101024698, COSV65568667; called by muse, mutect2, varscan2
- HPD | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 51/155 reads (33%) | catalogued as rs765923504, COSV56643393; called by muse, mutect2, varscan2
- HTRA3 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.814); catalogued as COSV100246241; called by muse, mutect2, varscan2
- ICAM2 | c.652C>G p.P218A | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.409); catalogued as COSV99856803, COSV99856840; called by muse, mutect2, varscan2
- ICAM2 | c.651G>A p.E217= | Splice Region (SNP) | VAF 9/54 reads (17%) | catalogued as COSV99856841; called by muse, mutect2, varscan2
- IL1RAPL1 | c.705C>A p.A235= | Splice Region (SNP) | VAF 13/21 reads (62%) | catalogued as COSV100145747; called by muse, mutect2, varscan2
- IL1RL1 | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.865); catalogued as rs772608146, COSV99293745; called by muse, mutect2, varscan2
- KANSL1 | c.2542-2A>T p.X848_splice (on ENST00000574590 / NM_001193465.2; = p.Q848L on NM_015443.4) | Splice Site (SNP) | VAF 19/54 reads (35%) | catalogued as COSV99294175; called by muse, mutect2, varscan2
- KAT6B | c.2115G>C p.E705D | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV99767493; called by muse, mutect2, varscan2
- KCNS1 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as COSV100067094; called by muse, varscan2
- KCNS3 | c.1082G>A p.W361* | Nonsense Mutation (SNP) | VAF 45/117 reads (38%) | catalogued as COSV100411054; called by muse, mutect2, varscan2
- KLC4 | c.308A>C p.Q103P | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99431489; called by muse, mutect2, varscan2
- KLF5 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100890503; called by muse, mutect2, varscan2
- LCT | c.829T>G p.F277V | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99928816; called by muse, mutect2, varscan2
- LILRB5 | c.662C>G p.S221C | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1176677024, COSV100300159; called by muse, mutect2, varscan2
- MAP3K12 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs1351746929, COSV57233708; called by muse, mutect2, varscan2
- METTL17 | c.853T>C p.W285R | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776649779, COSV100068493; called by muse, varscan2
- MMP16 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 101/287 reads (35%) | catalogued as COSV54152011, COSV54191186; called by muse, mutect2, varscan2
- MMP9 | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100812363; called by muse, mutect2, varscan2
- MRPL21 | c.10T>C p.S4P | Missense Mutation (SNP) | VAF 13/215 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.07); catalogued as COSV99661901; called by muse, mutect2
- MUC4 | c.12973G>T p.A4325S (on ENST00000463781 / NM_018406.7; = p.A89S on NM_004532.6) | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV57780234; called by muse, mutect2, varscan2
- NAV2 | c.856G>A p.A286T (on ENST00000396087 / NM_001244963.2; = p.A263T on NM_145117.5) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.003); catalogued as rs747098080, COSV100585043; called by muse, mutect2, varscan2
- NEBL | c.240G>C p.L80F | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV101012214; called by muse, mutect2, varscan2
- NPHS1 | c.2396G>C p.G799A | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV100799648; called by muse, mutect2, varscan2
- NRXN1 | c.1400G>T p.G467V | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs749766261, COSV100453794, COSV58446255; called by muse, mutect2, varscan2
- NTNG1 | c.1019C>G p.P340R | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV99635935; called by muse, mutect2, varscan2
- NUTM1 | c.2965T>A p.S989T | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV100148871; called by muse, mutect2, varscan2
- OR1S2 | c.54C>A p.N18K | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56919830; called by muse, mutect2, varscan2
- OR2M3 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 248/512 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV101513404; called by muse, mutect2, varscan2
- OR6K2 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs183333879, COSV62743136, COSV62743450; called by muse, mutect2, varscan2
- PAPPA2 | c.4387G>T p.D1463Y | Missense Mutation (SNP) | VAF 83/197 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100867668, COSV62813141; called by muse, mutect2, varscan2
- PAQR9 | c.202T>C p.C68R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100503711; called by muse, mutect2
- PCDH18 | c.3199A>G p.T1067A | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100787101; called by muse, mutect2, varscan2
- PHF14 | c.1821G>T p.R607S | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV101301780; called by muse, mutect2, varscan2
- PHOSPHO1 | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV99865319; called by muse, mutect2, varscan2
- PLEKHO2 | c.61A>G p.K21E | Missense Mutation (SNP) | VAF 53/250 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100060582; called by muse, mutect2, varscan2
- PNLIP | c.600G>T p.Q200H | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.238); catalogued as COSV100981670; called by muse, mutect2, varscan2
- PNLIP | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100981671; called by muse, mutect2, varscan2
- POGZ | c.1442T>C p.V481A | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV99652478; called by muse, mutect2, varscan2
- PPIP5K1 | c.4051C>T p.H1351Y (on ENST00000396923; = p.H1326Y on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.062); catalogued as rs370336137; called by muse, mutect2, varscan2
- PSMD1 | c.1688C>G p.A563G | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV100433409; called by muse, mutect2, varscan2
- PTPRK | c.2569C>A p.P857T (on ENST00000368215 / NM_001291984.2; = p.P858T on NM_002844.4) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV100950505; called by muse, mutect2, varscan2
- RAB1B | c.599G>C p.C200S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.213); catalogued as COSV100268341; called by muse, mutect2, varscan2
- RANBP2 | c.4637A>T p.Q1546L | Missense Mutation (SNP) | VAF 95/260 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as COSV99311475; called by muse, mutect2, varscan2
- RANBP2 | c.8830G>C p.D2944H | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99311476; called by muse, mutect2, varscan2
- RB1 | c.2077G>T p.E693* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as COSV57301553, COSV57333031; called by muse, mutect2, varscan2
- REG1B | c.346G>T p.G116W | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100521283; called by muse, mutect2, varscan2
- RING1 | c.877G>T p.D293Y | Missense Mutation (SNP) | VAF 132/369 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100761728, COSV63002285; called by muse, mutect2, varscan2
- SCUBE1 | c.349+2T>C p.X117_splice | Splice Site (SNP) | VAF 25/84 reads (30%) | catalogued as COSV51813609; called by muse, mutect2, varscan2
- SDK1 | c.6535G>T p.G2179C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as rs1335333246, COSV101268869; called by muse, mutect2, varscan2
- SERINC1 | c.80G>C p.R27P | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); catalogued as COSV100305090, COSV60101939; called by muse, mutect2, varscan2
- SERPINE1 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1379773181, COSV99776604; called by muse, mutect2, varscan2
- SGK3 | c.1408A>G p.I470V | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs202151244, COSV100616601; called by muse, mutect2, varscan2
- SHE | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs751979473, COSV59071195; called by muse, mutect2, varscan2
- SIGLEC6 | c.1029G>T p.R343S | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as COSV100585205; called by muse, mutect2, varscan2
- SIGLEC6 | c.1028G>T p.R343M | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100585206; called by muse, mutect2, varscan2
- SLC17A1 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99765634; called by muse, mutect2, varscan2
- SLC35G3 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 145/366 reads (40%) | catalogued as COSV99268334; called by muse, mutect2, varscan2
- SPAG9 | c.1337A>G p.D446G (on ENST00000262013 / NM_001130528.3; = p.D432G on NM_003971.6) | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV100004676; called by muse, mutect2, varscan2
- SPATA19 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV100141052, COSV54484855; called by muse, mutect2, varscan2
- SPTA1 | c.6885G>C p.E2295D | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.071); catalogued as rs767793235, COSV100934513; called by muse, mutect2, varscan2
- SRRM4 | c.1190G>T p.S397I | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99937940; called by muse, mutect2, varscan2
- STAG3 | c.3092T>A p.L1031Q | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100425709; called by muse, mutect2, varscan2
- TFE3 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100252392; called by muse, mutect2
- TLK1 | c.1165C>T p.Q389* | Nonsense Mutation (SNP) | VAF 65/184 reads (35%) | catalogued as COSV100687598; called by muse, mutect2, varscan2
- TLR6 | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV101126248; called by muse, mutect2, varscan2
- TOP3B | c.910G>T p.V304L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100592379; called by muse, mutect2, varscan2
- TRIM49 | c.995G>C p.G332A | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); catalogued as COSV100315925; called by muse, mutect2, varscan2
- TRIM49 | c.994G>T p.G332C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61671088; called by muse, mutect2, varscan2
- TRIP4 | c.1274A>T p.Q425L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV99974401; called by muse, mutect2, varscan2
- TRPM7 | c.5299G>A p.D1767N | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100539506; called by muse, mutect2, varscan2
- TSHR | c.905A>G p.N302S | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99991247; called by muse, mutect2, varscan2
- TTLL2 | c.1732A>T p.R578* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as COSV99514475; called by muse, mutect2, varscan2
- TTN | c.3106G>A p.E1036K (on ENST00000591111; = p.E990K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | PolyPhen probably damaging (0.994); catalogued as rs866375197, COSV100599109; called by muse, mutect2, varscan2
- UHRF1BP1 | c.844A>C p.T282P | Missense Mutation (SNP) | VAF 141/416 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV99511564; called by muse, mutect2
- UNC79 | c.6122C>T p.A2041V (on ENST00000393151 / NM_001346218.2; = p.A1864V on NM_020818.5) | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs200271627, COSV99826318; called by muse, mutect2, varscan2
- USP50 | c.877C>G p.H293D (on ENST00000616326; = p.H284D on NM_203494.5) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV101597704; called by muse, mutect2, varscan2
- VPS51 | c.1597G>T p.D533Y | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99659583; called by muse, mutect2, varscan2
- VTCN1 | c.288G>C p.M96I | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100061493; called by muse, mutect2, varscan2
- WARS1 | c.1294A>G p.K432E | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as rs1196714792, COSV100690060; called by muse, mutect2, varscan2
- ZGRF1 | c.2925G>A p.M975I | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100005367; called by muse, mutect2, varscan2
- ZNF285 | c.782A>C p.K261T | Missense Mutation (SNP) | VAF 96/220 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV100449888; called by muse, mutect2, varscan2
- ZNF530 | c.499C>G p.P167A | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV100252437, COSV60532526; called by muse, mutect2, varscan2
- ZNF8 | c.438G>C p.Q146H | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99544162, COSV99544522; called by muse, mutect2, varscan2
- ZPBP | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.138); catalogued as COSV99249236; called by muse, mutect2, varscan2
- ARID1B | c.2549_2553del p.P850Rfs*77 | Frame Shift Del (DEL) | VAF 24/126 reads (19%) | called by mutect2, pindel, varscan2
- COL26A1 | c.974del p.P325Qfs*24 (on ENST00000313669 / NM_001278563.3; = p.P323Qfs*24 on NM_133457.4) | Frame Shift Del (DEL) | VAF 41/134 reads (31%) | called by mutect2, pindel, varscan2
- DAPK3 | c.1049del p.H350Pfs*78 | Frame Shift Del (DEL) | VAF 6/8 reads (75%) | called by mutect2, varscan2
- DPH6 | c.506-4_517del p.X169_splice | Splice Site (DEL) | VAF 31/178 reads (17%) | called by mutect2, pindel, varscan2
- MROH5 | c.2798_2816+1del p.X933_splice | Splice Site (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel
- NAV1 | c.2529del p.S844Vfs*19 | Frame Shift Del (DEL) | VAF 90/438 reads (21%) | called by mutect2, pindel, varscan2
- OR2T2 | c.419G>T p.R140M | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- OR2T35 | c.416G>T p.R139M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by mutect2, varscan2
- PLXNA1 | c.2913del p.P972Lfs*15 | Frame Shift Del (DEL) | VAF 31/146 reads (21%) | called by mutect2, pindel, varscan2
- THBS3 | c.1715_1716del p.P572Qfs*8 | Frame Shift Del (DEL) | VAF 30/132 reads (23%) | called by mutect2, pindel, varscan2
- AATK | c.1899C>T p.A633= (on ENST00000326724 / NM_001080395.3; = p.A530= on NM_004920.2) | Silent (SNP) | VAF 4/57 reads (7%) | catalogued as rs1488136708, COSV100352573; called by muse, mutect2
- ANKRD7 | c.486A>C p.L162= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV99500973; called by muse, mutect2, varscan2
- APAF1 | c.1833C>T p.V611= (on ENST00000551964 / NM_181861.2; = p.V600= on NM_001160.3) | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as rs773318734, COSV100452347; called by muse, mutect2, varscan2
- ARHGAP20 | c.1371A>C p.V457= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV99503324; called by muse, mutect2, varscan2
- C9orf50 | c.930C>A p.S310= | Silent (SNP) | VAF 45/142 reads (32%) | catalogued as COSV100992307, COSV65252468; called by muse, mutect2, varscan2
- CFAP54 | c.5430T>C p.C1810= | Silent (SNP) | VAF 61/184 reads (33%) | catalogued as COSV100733012; called by muse, mutect2, varscan2
- CHRNA7 | c.1131G>T p.P377= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as COSV60977117; called by muse, mutect2, varscan2
- CLVS2 | c.706C>T p.L236= | Silent (SNP) | VAF 39/142 reads (27%) | catalogued as COSV99252294; called by muse, mutect2, varscan2
- DCAF4L2 | c.63G>A p.V21= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as COSV100150415, COSV100150585; called by muse, mutect2, varscan2
- DMTF1 | c.1416A>T p.S472= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV100487301; called by muse, mutect2, varscan2
- DNAH7 | c.9306C>T p.N3102= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs200369750, COSV100414211; called by mutect2, varscan2
- DNAH9 | c.7536G>T p.T2512= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV52382162, COSV99304658; called by muse, mutect2
- FREM2 | c.9393A>T p.A3131= | Silent (SNP) | VAF 33/51 reads (65%) | catalogued as rs1489975501, COSV99747365; called by muse, varscan2
- HECTD4 | c.8187A>T p.P2729= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV101106922; called by muse, mutect2, varscan2
- IGKV1-12 | c.138G>T p.R46= | Silent (SNP) | VAF 35/204 reads (17%) | called by muse, mutect2, varscan2
- ITIH5 | c.234T>C p.S78= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as rs779347486, COSV99903975; called by muse, mutect2, varscan2
- KCNG2 | c.510G>A p.P170= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1392219292, COSV100301671; called by muse, mutect2, varscan2
- KDR | c.2587A>C p.R863= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as COSV99816914; called by muse, mutect2, varscan2
- KIAA0319 | c.987C>A p.P329= | Silent (SNP) | VAF 61/190 reads (32%) | catalogued as COSV100985294; called by muse, mutect2, varscan2
- LRP1B | c.777C>A p.L259= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV101253888; called by muse, mutect2, varscan2
- MEGF9 | c.354G>T p.A118= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100879330; called by muse, mutect2
- NEURL2 | c.558C>T p.R186= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as COSV99509705; called by muse, mutect2, varscan2
- NLRP3 | c.2541A>T p.S847= | Silent (SNP) | VAF 54/140 reads (39%) | catalogued as COSV100275473; called by muse, mutect2, varscan2
- OR10G9 | c.102G>T p.V34= | Silent (SNP) | VAF 63/244 reads (26%) | catalogued as COSV100901495; called by muse, varscan2
- OR10Q1 | c.594C>T p.R198= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV100372167; called by muse, mutect2, varscan2
- OR11G2 | c.496C>A p.R166= | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as COSV100639925, COSV62131721; called by muse, mutect2, varscan2
- PCDHA2 | c.1725C>A p.G575= | Silent (SNP) | VAF 55/108 reads (51%) | catalogued as rs782143025, COSV65367026, COSV65368460; called by muse, mutect2, varscan2
- PCDHA5 | c.2292C>T p.P764= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV100972159; called by muse, mutect2, varscan2
- PCDHB9 | c.1908C>T p.A636= | Silent (SNP) | VAF 35/63 reads (56%) | called by muse, mutect2, varscan2
- PITPNM1 | c.2775G>C p.T925= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV99653577; called by muse, mutect2, varscan2
- PTPRM | c.2358G>A p.V786= | Silent (SNP) | VAF 47/152 reads (31%) | catalogued as COSV100155614; called by muse, mutect2, varscan2
- SC5D | c.480T>A p.P160= | Silent (SNP) | VAF 107/303 reads (35%) | catalogued as COSV99872989; called by muse, mutect2, varscan2
- SDE2 | c.408G>A p.R136= | Silent (SNP) | VAF 59/257 reads (23%) | catalogued as COSV99682522; called by muse, mutect2, varscan2
- SDK1 | c.6534G>T p.A2178= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs1390018945, COSV67382650; called by muse, mutect2, varscan2
- SEPTIN4 | c.1005C>T p.V335= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV100400242; called by muse, mutect2, varscan2
- SHD | c.225G>A p.K75= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV101619027; called by muse, mutect2, varscan2
- SOX18 | c.1026G>A p.G342= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100450509; called by muse, mutect2, varscan2
- TOR1A | c.438G>A p.L146= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100693890; called by muse, mutect2, varscan2
- TXNDC11 | c.2757G>C p.T919= (on ENST00000356957 / NM_001303447.2; = p.T892= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 76/117 reads (65%) | catalogued as COSV51603679, COSV99297384; called by muse, mutect2, varscan2
- UNC13C | c.2493G>A p.G831= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV99513000; called by muse, mutect2, varscan2
- VARS2 | c.2583T>A p.A861= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV100422717; called by muse, mutect2, varscan2
- WSCD1 | c.858C>T p.P286= | Silent (SNP) | VAF 171/311 reads (55%) | catalogued as COSV100496434, COSV58495624, COSV58496001; called by muse, mutect2, varscan2
- FAM83D | chr20:38926403 G>T | 5'Flank (SNP) | VAF 27/81 reads (33%) | catalogued as rs763233937, COSV99465065; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85654C>T | Intron (SNP) | VAF 84/219 reads (38%) | catalogued as rs1560949494; called by muse, mutect2, varscan2
- MSLNL | c.504-14C>A | Intron (SNP) | VAF 23/40 reads (58%) | catalogued as COSV99558001; called by muse, mutect2, varscan2
- PHF20L1 | c.1637-222G>C | Intron (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
